Gene-level copy-number profile of tumor specimen TCGA-CH-5792-01A from TCGA case TCGA-CH-5792, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.5 years (21,002 days).
Specimen TCGA-CH-5792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.f9cf45fb-7b63-43c4-bd3f-04c2c2559bf6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5792-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7ece83e-7755-454d-8a1e-0696bd4c0708

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 6,528; copy number 2: 53,129; copy number 4: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5792-01A-11D-1574-01): tumor purity 0.38, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:103,866,023–104,026,763, 3 genes: AL590608.1, R3HDM2P2, NPM1P10.
- chr12:10,824,960–11,171,608, 1 gene (within-gene range 0–1): PRH1.
- chr12:10,845,849–12,724,011, 61 genes (broad region; genes not listed).
- chr12:12,764,649–12,764,743, 1 gene: MIR613.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
